Gene-level copy-number profile of tumor specimen TCGA-CC-A5UD-01A from TCGA case TCGA-CC-A5UD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.7 years (16,702 days).
Specimen TCGA-CC-A5UD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.aeb99006-bce5-4bd1-975d-a0bddc47d723.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A5UD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e39726ee-ee8f-495b-8179-43bd05935ce0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,365; copy number 2: 25,861; copy number 3: 16,632; copy number 4: 9,434; copy number 5: 2,247; copy number 6: 223; copy number 7: 1,053.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A5UD-01A-11D-A28W-01): tumor purity 0.85, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,523 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–202,189,455, 1,536 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 6 (within-gene range 3–6): RIMS2.
- chr8:103,768,281–145,066,685, 600 genes, copy number 6–7 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 7 (broad region; genes not listed).
- chr13:55,535,697–55,583,524, 1 gene, copy number 5: AL354821.1.

Autosomal genes at a single copy (total copy number 1): 1,944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
